Somatic mutation profile of tumor specimen MMRF_2697_1_BM_CD138pos (aliquot MMRF_2697_1_BM_CD138pos_T1_KHS5U_L14841) from MMRF case MMRF_2697, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 53.1 years (19,382 days).
Specimen MMRF_2697_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 45f20ac9-815f-4564-aef9-5ddf7c3b99f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2697_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2697_1_PB_WBC_C2_KHS5U_L14815; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a4e02a3f-67c8-46a3-ada1-6262b3bce595

The open-access MAF lists 94 somatic variants for this specimen: 30 protein-altering or splice-affecting, 12 silent, 52 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 27, 3'UTR 27, Intron 14, Silent 12, 5'UTR 6, RNA 2, 5'Flank 2, Splice Region 1, Nonsense Mutation 1, 3'Flank 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.3701A>G p.N1234S | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs1396912154; called by muse, mutect2, varscan2
- ARL3 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1443415801; called by muse, mutect2
- CASKIN2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.837); catalogued as rs756458899; called by muse, mutect2, varscan2
- CDKL2 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 175/328 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56732651; called by muse, mutect2, varscan2
- CFAP47 | c.4244C>A p.A1415E | Missense Mutation (SNP) | VAF 5/116 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs1189810562; called by muse, mutect2
- CLCN6 | c.2240G>A p.R747Q | Missense Mutation (SNP) | VAF 61/181 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs933086400, COSV100412002; called by muse, mutect2, varscan2
- HSPB8 | c.266dup p.P90Tfs*37 | Frame Shift Ins (INS) | VAF 43/126 reads (34%) | catalogued as rs773017653; called by mutect2, varscan2
- IGLV3-1 | c.304G>A p.A102T | Missense Mutation (SNP) | VAF 85/216 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as rs371563415; called by muse, varscan2
- MMUT | c.700C>T p.P234S | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs1442489589, COSV51272557; called by muse, mutect2, varscan2
- MSX2 | c.770C>T p.T257M | Missense Mutation (SNP) | VAF 61/276 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs752824647, COSV53326517; called by muse, mutect2, varscan2
- NAALADL2 | c.227A>G p.H76R | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs1033378581; called by muse, mutect2
- PCDH15 | c.4156C>A p.L1386I | Missense Mutation (SNP) | VAF 35/83 reads (42%) | SIFT tolerated (0.18); PolyPhen benign (0.241); catalogued as COSV57346988; called by muse, mutect2, varscan2
- PTPN13 | c.6053C>T p.S2018L (on ENST00000411767 / NM_080683.3; = p.S1999L on NM_006264.3) | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs764113622, COSV57412025; called by muse, mutect2, varscan2
- QRSL1 | c.1400C>G p.S467* | Nonsense Mutation (SNP) | VAF 12/191 reads (6%) | catalogued as COSV100945413; called by muse, mutect2
- RP1L1 | c.2696C>T p.P899L | Missense Mutation (SNP) | VAF 46/91 reads (51%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs779849753, COSV101223427; ClinVar: benign; called by muse, mutect2, varscan2
- SPEF2 | c.4492G>A p.V1498M | Missense Mutation (SNP) | VAF 21/187 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.087); catalogued as COSV57427329; called by muse, mutect2, varscan2
- TLR9 | c.2155G>A p.G719S | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.057); catalogued as rs375556098; called by muse, mutect2, varscan2
- WASHC5 | c.731C>T p.P244L | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.577); catalogued as rs759414886, COSV100572510; called by muse, mutect2, varscan2
- ZNF804B | c.3460G>A p.E1154K | Missense Mutation (SNP) | VAF 20/222 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770550850; called by muse, mutect2
- CHD9 | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 33/160 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- IGHV2-70D | c.250C>G p.L84V | Missense Mutation (SNP) | VAF 36/124 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); called by muse, varscan2
- KCNH8 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 20/302 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); called by muse, mutect2
- LMTK3 | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 64/116 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- LTBP1 | c.1875A>G p.Q625= (on ENST00000404816 / NM_206943.4; = p.Q299= on NM_000627.4) | Splice Region (SNP) | VAF 74/224 reads (33%) | called by muse, mutect2
- PLCD3 | c.2188G>T p.A730S | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); called by muse, mutect2
- RRH | c.915G>A p.M305I | Missense Mutation (SNP) | VAF 129/503 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A10 | c.199C>A p.H67N | Missense Mutation (SNP) | VAF 14/195 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2
- SLC51A | c.462G>A p.M154I | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ZFHX4 | c.1817A>G p.D606G | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- ZNF239 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 68/163 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ACP6 | c.600C>A p.V200= | Silent (SNP) | VAF 32/93 reads (34%) | called by muse, mutect2, varscan2
- BAAT | c.1008C>T p.H336= | Silent (SNP) | VAF 113/191 reads (59%) | catalogued as rs144681311; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD22 | c.1521C>T p.D507= | Silent (SNP) | VAF 32/174 reads (18%) | catalogued as rs757060882, COSV50049513; called by muse, mutect2, varscan2
- CHRNA7 | c.61C>T p.L21= | Silent (SNP) | VAF 26/164 reads (16%) | catalogued as COSV60974496; called by muse, mutect2, varscan2
- IGHV1-69 | c.225T>G p.G75= | Silent (SNP) | VAF 88/253 reads (35%) | catalogued as rs11557989; called by muse, varscan2
- IGLV4-3 | c.141C>T p.H47= | Silent (SNP) | VAF 47/145 reads (32%) | catalogued as rs763898216; called by muse, mutect2, varscan2
- INA | c.807C>T p.R269= | Silent (SNP) | VAF 41/168 reads (24%) | called by muse, mutect2, varscan2
- N4BP2 | c.2922G>A p.S974= | Silent (SNP) | VAF 52/267 reads (19%) | catalogued as rs752817547; called by muse, mutect2, varscan2
- PNPLA5 | c.924G>A p.E308= | Silent (SNP) | VAF 26/183 reads (14%) | called by muse, mutect2, varscan2
- RASAL3 | c.837T>A p.A279= | Silent (SNP) | VAF 52/181 reads (29%) | called by muse, mutect2, varscan2
- SEM1 | c.207A>C p.T69= | Silent (SNP) | VAF 18/74 reads (24%) | called by muse, varscan2
- ST8SIA3 | c.990A>T p.T330= | Silent (SNP) | VAF 84/276 reads (30%) | called by muse, mutect2
- ARHGEF11 | c.*310G>A | 3'UTR (SNP) | VAF 19/141 reads (13%) | catalogued as rs772150271; called by muse, mutect2, varscan2
- BCL7A | chr12:122021492 C>T | 5'Flank (SNP) | VAF 68/195 reads (35%) | catalogued as COSV55846308, COSV55846472; called by muse, varscan2
- BMP5 | c.*1461G>A | 3'UTR (SNP) | VAF 21/70 reads (30%) | catalogued as rs1404912392, COSV63702783; called by muse, mutect2, varscan2
- CADM2 | c.-2C>A | 5'UTR (SNP) | VAF 153/310 reads (49%) | called by muse, mutect2, varscan2
- CD36 | c.120+87C>A | Intron (SNP) | VAF 13/23 reads (57%) | called by muse, varscan2
- CDS2 | c.*1177G>A | 3'UTR (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- CELSR2 | c.-18G>A | 5'UTR (SNP) | VAF 7/28 reads (25%) | catalogued as rs752216697; called by muse, mutect2, varscan2
- CHTF8P1 | n.252C>T | RNA (SNP) | VAF 62/80 reads (78%) | called by muse, mutect2, varscan2
- COL4A4 | c.*2126A>T | 3'UTR (SNP) | VAF 17/61 reads (28%) | called by muse, mutect2, varscan2
- DCK | c.757-634A>C | Intron (SNP) | VAF 5/33 reads (15%) | called by muse, mutect2
- FGF10 | c.*1191G>A | 3'UTR (SNP) | VAF 17/124 reads (14%) | catalogued as rs530762348, COSV52940429; called by muse, mutect2, varscan2
- GPR179 | c.*85A>T | 3'UTR (SNP) | VAF 71/193 reads (37%) | called by muse, mutect2, varscan2
- HDAC7 | chr12:47783408 A>C | 3'Flank (SNP) | VAF 26/161 reads (16%) | called by muse, mutect2, varscan2
- HIPK2 | c.*10004T>C | 3'UTR (SNP) | VAF 6/101 reads (6%) | called by muse, mutect2
- HLX | c.-292G>T | 5'UTR (SNP) | VAF 10/46 reads (22%) | called by muse, mutect2, varscan2
- IGFBP5 | c.*3083C>T | 3'UTR (SNP) | VAF 15/207 reads (7%) | called by muse, mutect2
- IGFN1 | c.2919+29G>A | Intron (SNP) | VAF 35/101 reads (35%) | called by muse, mutect2, varscan2
- IGLL5 | c.*17_*18dup | 3'UTR (INS) | VAF 59/280 reads (21%) | called by mutect2, pindel, varscan2
- IRX4 | c.298-172A>C | Intron (SNP) | VAF 4/19 reads (21%) | called by muse, mutect2
- ITFG2 | c.1240+18C>T | Intron (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2, varscan2
- KCNC1 | c.*4044G>T | 3'UTR (SNP) | VAF 16/124 reads (13%) | catalogued as rs879162160; called by muse, mutect2
- KRT80 | c.-60C>T | 5'UTR (SNP) | VAF 5/41 reads (12%) | catalogued as rs1047752889; called by muse, mutect2
- LRRC40 | c.-17G>C | 5'UTR (SNP) | VAF 6/112 reads (5%) | called by muse, mutect2
- MIR5195 | chr14:106851314 G>C | 5'Flank (SNP) | VAF 61/153 reads (40%) | catalogued as rs573318832; called by muse, mutect2, varscan2
- MMP17 | c.969-47C>T | Intron (SNP) | VAF 15/49 reads (31%) | catalogued as rs200612244; called by muse, mutect2
- MYT1L | c.*2436T>C | 3'UTR (SNP) | VAF 18/70 reads (26%) | called by muse, mutect2, varscan2
- NECTIN3-AS1 | n.865A>C | RNA (SNP) | VAF 52/97 reads (54%) | called by muse, mutect2, varscan2
- NPR3 | c.*5375dup | 3'UTR (INS) | VAF 13/123 reads (11%) | called by mutect2, pindel, varscan2
- OBSCN | c.18662-2513A>G | Intron (SNP) | VAF 14/246 reads (6%) | catalogued as rs1222644073; called by muse, mutect2
- PHF20L1 | c.*2100T>C | 3'UTR (SNP) | VAF 43/120 reads (36%) | called by muse, mutect2, varscan2
- PRDM1 | c.*483_*486del | 3'UTR (DEL) | VAF 9/97 reads (9%) | called by mutect2, pindel, varscan2
- PREB | c.325+50G>A | Intron (SNP) | VAF 42/92 reads (46%) | catalogued as rs1338933044; called by muse, mutect2, varscan2
- PTPRN2 | c.*74G>A | 3'UTR (SNP) | VAF 31/360 reads (9%) | catalogued as COSV101234064, COSV101235912; called by muse, mutect2
- PTRH2 | c.1-1714G>A | Intron (SNP) | VAF 23/54 reads (43%) | catalogued as rs1366442489; called by muse, mutect2, varscan2
- PXDN | c.*866G>A | 3'UTR (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- QSOX2 | c.*1285T>A | 3'UTR (SNP) | VAF 20/60 reads (33%) | called by muse, mutect2, varscan2
- RAB14 | c.*1591C>A | 3'UTR (SNP) | VAF 16/121 reads (13%) | called by muse, mutect2, varscan2
- RABGAP1 | c.*250C>T | 3'UTR (SNP) | VAF 8/233 reads (3%) | catalogued as rs1333970133; called by muse, mutect2
- RAPGEF2 | c.1652+82C>T | Intron (SNP) | VAF 12/109 reads (11%) | called by muse, mutect2, varscan2
- SIDT2 | c.869-64G>A | Intron (SNP) | VAF 5/77 reads (6%) | called by muse, mutect2
- SIX5 | c.-25G>T | 5'UTR (SNP) | VAF 75/139 reads (54%) | called by muse, mutect2, varscan2
- SRGAP1 | c.*3669C>T | 3'UTR (SNP) | VAF 8/75 reads (11%) | catalogued as rs1489795636; called by muse, mutect2, varscan2
- SUGP1 | c.1244-115G>A | Intron (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- SYNE1 | c.26154-3819G>T | Intron (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- TACC2 | c.*47G>A | 3'UTR (SNP) | VAF 134/384 reads (35%) | catalogued as rs777282532; called by muse, mutect2, varscan2
- THBD | c.*1071C>A | 3'UTR (SNP) | VAF 4/71 reads (6%) | called by muse, mutect2
- TMEM213 | c.*127G>A | 3'UTR (SNP) | VAF 39/85 reads (46%) | catalogued as rs1365618647; called by muse, mutect2, varscan2
- TNFSF15 | c.*236G>A | 3'UTR (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- TRANK1 | c.*1161A>G | 3'UTR (SNP) | VAF 20/199 reads (10%) | called by muse, mutect2
- YTHDC1 | c.*3146del | 3'UTR (DEL) | VAF 27/121 reads (22%) | called by mutect2, pindel, varscan2
- ZFYVE16 | c.*1556G>T | 3'UTR (SNP) | VAF 3/42 reads (7%) | called by muse, mutect2
- ZSCAN18 | c.746-141A>T | Intron (SNP) | VAF 4/26 reads (15%) | called by muse, mutect2
